Somatic mutation profile of tumor specimen ALCH-B2AO-TTP1-A (aliquot ALCH-B2AO-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2AO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.4 years (22,071 days).
Specimen ALCH-B2AO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3971e4df-eb66-432e-85a6-a3029a5c77ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AO-NB1-A (Blood Derived Normal), aliquot ALCH-B2AO-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd9c6ea8-aa44-4a20-a3b0-30a2bd5f28c2

The open-access MAF lists 1,634 somatic variants for this specimen: 1,122 protein-altering or splice-affecting, 330 silent, 182 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 959, Silent 330, Nonsense Mutation 98, Intron 81, RNA 35, Splice Site 32, 3'UTR 26, Splice Region 15, 3'Flank 15, 5'UTR 13, 5'Flank 12, Frame Shift Del 10.

Variants (750 of 1,634; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNB2 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs74315291, CM002752, CM010187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 75/656 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 36/215 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs763443454; called by muse, mutect2, varscan2
- AASS | c.1431G>T p.M477I | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100741724; called by muse, mutect2
- ABCC2 | c.2620G>T p.V874F | Missense Mutation (SNP) | VAF 32/472 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.445); catalogued as rs547147518; called by muse, mutect2
- ABCC2 | c.2620+1G>T p.X874_splice | Splice Site (SNP) | VAF 34/468 reads (7%) | catalogued as COSV64988347; called by muse, mutect2
- AC004593.2 | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 41/695 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56092507, COSV99765489; called by muse, mutect2
- AC013477.1 | c.2342A>T p.H781L | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.175); catalogued as rs144429523; called by muse, mutect2, varscan2
- AC136428.1 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 137/784 reads (17%) | catalogued as rs770193359, COSV101434935; called by muse, mutect2, varscan2
- ACAP3 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV100686245; called by muse, mutect2
- ACTL9 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61004787; called by muse, mutect2
- ADAMTS20 | c.2163G>T p.K721N | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs551169111, COSV101238630; called by muse, mutect2
- ADAMTSL4 | c.2383-8C>A | Splice Region (SNP) | VAF 43/345 reads (12%) | catalogued as rs1433296261; called by muse, mutect2, varscan2
- ADCK2 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 19/432 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs1377161063; called by muse, mutect2
- ADGB | c.2690C>T p.T897I | Missense Mutation (SNP) | VAF 20/593 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1301045682; called by muse, mutect2
- ADGRB2 | c.2536G>T p.V846L | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57071002; called by muse, mutect2
- ALK | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV66574662; called by muse, mutect2
- ANK1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 58/786 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs992731033; called by muse, mutect2
- ANKRD30B | c.3275C>A p.A1092D | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV57704660; called by muse, mutect2, varscan2
- ANKRD31 | c.5074C>A p.P1692T | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV57158383; called by muse, mutect2
- ANKS1A | c.2347G>T p.G783W | Missense Mutation (SNP) | VAF 67/494 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755330516; called by muse, mutect2, varscan2
- ANO2 | c.168C>A p.C56* (on ENST00000356134 / NM_001278597.3; = p.C60* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 63/316 reads (20%) | catalogued as rs779647848; called by muse, mutect2, varscan2
- ANO8 | c.3211G>C p.G1071R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV50201874; called by muse, mutect2, varscan2
- AOAH | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 52/806 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99332771; called by muse, mutect2
- APC | c.3976G>T p.V1326L | Missense Mutation (SNP) | VAF 140/781 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV57397245; called by muse, mutect2, varscan2
- ARHGAP21 | c.1378C>A p.Q460K | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57611096; called by muse, mutect2
- ARHGAP25 | c.1268G>T p.S423I (on ENST00000409202 / NM_001007231.3; = p.S415I on NM_014882.3) | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs565639760; called by muse, mutect2, varscan2
- ARMCX4 | c.887C>G p.T296S (on ENST00000433011; = p.T192S on NM_001256155.2) | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.243); catalogued as rs781859156; called by muse, mutect2, varscan2
- AURKC | c.800G>A p.R267Q (on ENST00000302804 / NM_001015878.2; = p.R233Q on NM_003160.3) | Missense Mutation (SNP) | VAF 56/757 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs765491946, COSV57140942; called by muse, mutect2
- BMP7 | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67780993; called by muse, mutect2, varscan2
- BPIFB1 | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV53606159; called by muse, mutect2
- BSN | c.7846G>T p.D2616Y | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99608564; called by muse, mutect2
- BTK | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 99/708 reads (14%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.991); catalogued as CM952088, COSV58118475; called by muse, mutect2, varscan2
- BTN3A3 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.23); catalogued as COSV55074307; called by muse, mutect2, varscan2
- BTNL3 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 89/351 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV61564776; called by muse, mutect2, varscan2
- C10orf71 | c.2675A>T p.E892V | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV60513595; called by muse, mutect2
- C20orf194 | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as COSV99330220; called by muse, mutect2
- C4BPB | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs907003573; called by muse, mutect2
- C9orf24 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.726); catalogued as rs868752559; called by muse, mutect2
- CCDC85C | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs961813336; called by muse, mutect2, varscan2
- CD163 | c.1069C>A p.H357N | Missense Mutation (SNP) | VAF 48/695 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63131365; called by muse, mutect2
- CD163 | c.1068T>A p.N356K | Missense Mutation (SNP) | VAF 48/706 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.338); catalogued as COSV100775722; called by muse, mutect2
- CD163L1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs752758471; called by muse, mutect2, varscan2
- CD200 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 46/573 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59862055; called by muse, mutect2
- CDC14C | c.488C>A p.S163Y (on ENST00000428251; = p.S56Y on NM_152627.3) | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1239861757; called by muse, mutect2, varscan2
- CDH10 | c.2096G>T p.R699L | Missense Mutation (SNP) | VAF 113/820 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV52568195; called by muse, mutect2, varscan2
- CEBPA | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV57198689; called by muse, mutect2
- CELF3 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as COSV51884042; called by muse, mutect2
- CELSR1 | c.6367G>C p.E2123Q | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs774751216, COSV53097126; called by muse, mutect2
- CGAS | c.1136_1138del p.F379del | In Frame Del (DEL) | VAF 30/237 reads (13%) | catalogued as rs766646901; called by mutect2, pindel, varscan2
- CHRNA3 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58775382; called by muse, mutect2, varscan2
- CHRNA6 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV52379058, COSV99373095, COSV99373303; called by muse, mutect2
- CHRNB2 | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 21/531 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872568; called by muse, mutect2
- CKB | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs11545347; called by muse, mutect2, varscan2
- CLCA2 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 72/649 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1161315518; called by muse, mutect2, varscan2
- CLCN1 | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 134/750 reads (18%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.998); catalogued as CD110550; called by muse, mutect2, varscan2
- COL12A1 | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 55/521 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV59405936; called by muse, mutect2, varscan2
- COL12A1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 33/802 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV59388481; called by muse, mutect2
- COL18A1 | c.1909G>A p.E637K (on ENST00000359759 / NM_130444.3; = p.E402K on NM_030582.4) | Missense Mutation (SNP) | VAF 49/492 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1475241395, COSV62701468; called by muse, mutect2, varscan2
- COL2A1 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 53/592 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.613); catalogued as CD034337; called by muse, mutect2
- COL4A5 | c.2750G>T p.G917V | Missense Mutation (SNP) | VAF 76/712 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60369398; called by muse, mutect2, varscan2
- COL4A5 | c.4304G>T p.R1435L | Missense Mutation (SNP) | VAF 33/384 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100087649; called by muse, mutect2
- COL6A3 | c.6940G>T p.G2314* | Nonsense Mutation (SNP) | VAF 27/377 reads (7%) | catalogued as COSV55087998; called by muse, mutect2
- COL6A6 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.878); catalogued as COSV62040171; called by muse, mutect2, varscan2
- COLEC12 | c.1520C>A p.P507H | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV68372544; called by muse, mutect2, varscan2
- COMMD10 | c.41+7G>A | Splice Region (SNP) | VAF 46/352 reads (13%) | catalogued as rs775881946; called by muse, mutect2, varscan2
- CPA5 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1029445973; called by muse, mutect2
- CSGALNACT1 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs757114911; called by muse, mutect2, varscan2
- CSMD2 | c.2653G>C p.V885L | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as rs141404520; called by muse, mutect2, varscan2
- CSMD3 | c.4436A>G p.D1479G (on ENST00000297405 / NM_001363185.1; = p.D1375G on NM_052900.3) | Missense Mutation (SNP) | VAF 32/600 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV52240042; called by muse, mutect2
- CSPP1 | c.2527C>T p.R843W (on ENST00000676605; = p.R802W on NM_024790.6) | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757384412, COSV99138459; called by muse, mutect2, varscan2
- CTIF | c.432G>T p.G144= | Splice Region (SNP) | VAF 28/418 reads (7%) | catalogued as COSV99836853; called by muse, mutect2
- CYP39A1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 64/600 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV99242639; called by muse, mutect2
- CYP7A1 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 48/457 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV56963769, COSV56964129; called by muse, mutect2, varscan2
- DAGLB | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326348907; called by muse, mutect2, varscan2
- DCAF12L1 | c.252del p.E85Sfs*3 | Frame Shift Del (DEL) | VAF 46/265 reads (17%) | catalogued as COSV64422725; called by mutect2, pindel, varscan2
- DCAF8L1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.145); catalogued as COSV71595266; called by muse, mutect2
- DCC | c.2267G>C p.R756P | Missense Mutation (SNP) | VAF 68/597 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59110821; called by muse, mutect2, varscan2
- DCLK3 | c.1558G>C p.V520L | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV69362877; called by muse, mutect2, varscan2
- DHRS12 | c.450T>A p.G150= (on ENST00000444610 / NM_001377930.1; = p.G101= on NM_024705.2 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 40/328 reads (12%) | catalogued as rs763292178; called by muse, mutect2, varscan2
- DHX15 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 48/630 reads (8%) | catalogued as COSV100391924; called by muse, mutect2
- DLGAP1 | c.562C>A p.R188S | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59802690; called by muse, mutect2, varscan2
- DMXL1 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60721764; called by muse, mutect2, varscan2
- DNAAF5 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 42/582 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200573334, COSV52415192; called by muse, mutect2
- DNAH2 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 79/561 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs369805347; called by muse, mutect2, varscan2
- DNAH5 | c.8298G>T p.L2766F | Missense Mutation (SNP) | VAF 75/607 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770788944; called by muse, mutect2, varscan2
- DNAH9 | c.9499C>A p.L3167M | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99304277; called by muse, mutect2, varscan2
- DOCK1 | c.4928G>T p.R1643L | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54733870, COSV54762409; called by muse, mutect2
- DOCK4 | c.2056G>A p.V686M | Missense Mutation (SNP) | VAF 99/773 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs753651816, COSV70237204; called by muse, mutect2, varscan2
- DPEP1 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.077); catalogued as rs1168085525; called by muse, varscan2
- DPPA2 | c.545C>A p.P182Q | Missense Mutation (SNP) | VAF 44/497 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72118240; called by muse, mutect2
- ECEL1 | c.2055+1G>A p.X685_splice | Splice Site (SNP) | VAF 23/332 reads (7%) | catalogued as rs1427669165; called by muse, mutect2
- EGFLAM | c.2701C>A p.L901I (on ENST00000354891 / NM_001205301.2; = p.L893I on NM_152403.4) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); catalogued as rs1206794025; called by muse, mutect2
- EIF4A2 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV99961391; called by muse, mutect2
- ELMO3 | c.1574G>T p.R525L (on ENST00000652269; = p.R472L on NM_024712.5) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58527022; called by muse, mutect2, varscan2
- ENPP2 | c.2539C>A p.P847T (on ENST00000075322 / NM_001040092.3; = p.P899T on NM_006209.5) | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV50014644; called by muse, mutect2, varscan2
- EPB41L1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs775455374; called by muse, mutect2
- EPHA3 | c.2864G>T p.G955V | Missense Mutation (SNP) | VAF 66/398 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464031640; called by muse, mutect2, varscan2
- EYS | c.5828C>A p.T1943N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as COSV65484986; called by muse, mutect2
- FAM135B | c.2517G>T p.Q839H | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs770271569, COSV52710401; called by muse, mutect2, varscan2
- FAM47B | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 69/504 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100264248; called by muse, mutect2, varscan2
- FAM47C | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 35/458 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63729778; called by muse, mutect2
- FAM71F1 | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100171162; called by muse, mutect2
- FANCL | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV52074982; called by muse, mutect2
- FASN | c.5801G>T p.R1934L | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV60760006; called by muse, mutect2, varscan2
- FAT4 | c.10142G>C p.G3381A | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58703542; called by muse, mutect2, varscan2
- FBLN1 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53053083; called by muse, mutect2
- FCAR | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV62028414; called by muse, mutect2, varscan2
- FCRLA | c.937C>A p.P313T (on ENST00000367959; = p.P290T on NM_032738.4) | Missense Mutation (SNP) | VAF 66/415 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV52684992; called by muse, mutect2, varscan2
- FKBP8 | c.1099A>T p.M367L (on ENST00000222308 / NM_001308373.2; = p.M368L on NM_012181.5) | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as COSV55891212; called by muse, mutect2
- FLG | c.5550A>T p.E1850D | Missense Mutation (SNP) | VAF 28/635 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.178); catalogued as rs1199177044; called by muse, mutect2
- FOXI1 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60390329; called by muse, mutect2, varscan2
- FOXS1 | c.184T>A p.W62R | Missense Mutation (SNP) | VAF 88/543 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99639466; called by muse, mutect2, varscan2
- FREM3 | c.2726C>A p.T909K | Missense Mutation (SNP) | VAF 46/550 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs778527990, COSV61681241; called by muse, mutect2
- FRRS1L | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 87/433 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV101643931; called by muse, mutect2, varscan2
- G2E3 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52838833; called by muse, mutect2, varscan2
- GABRA2 | c.59G>T p.W20L | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.029); catalogued as COSV62915444; called by muse, mutect2, varscan2
- GGH | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 50/541 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478935; called by muse, mutect2
- GHRHR | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201403615; called by muse, mutect2
- GLP1R | c.885-1G>T p.X295_splice | Splice Site (SNP) | VAF 36/174 reads (21%) | catalogued as COSV64715029; called by muse, mutect2, varscan2
- GLRA3 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56861113; called by muse, varscan2
- GP5 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as rs763048450, COSV59877562; called by mutect2, varscan2
- GPR26 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV52933248; called by muse, mutect2, varscan2
- GRID2IP | c.2876G>A p.R959H | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1476503705; called by muse, mutect2, varscan2
- GRIN2A | c.3123T>A p.N1041K | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.5); catalogued as rs574425467; called by muse, mutect2, varscan2
- GTF3C1 | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62241347; called by muse, mutect2, varscan2
- GUSB | c.850G>C p.G284R | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs756721679; called by muse, mutect2, varscan2
- H2AC4 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 107/489 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52518212, COSV52518824; called by muse, mutect2, varscan2
- HAL | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 45/624 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV54118369; called by muse, mutect2
- HEPN1 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV53432651; called by muse, mutect2
- HPSE2 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 66/611 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV65193324; called by muse, mutect2, varscan2
- ICAM5 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs762526366, COSV55748086; called by muse, mutect2, varscan2
- IFT52 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV65974872; called by muse, mutect2
- IFT88 | c.1512del p.F504Lfs*17 (on ENST00000319980 / NM_001318493.2; = p.F495Lfs*17 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | catalogued as COSV100179881; called by mutect2, pindel
- IGDCC4 | c.2434G>A p.G812S | Missense Mutation (SNP) | VAF 50/469 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs368140698; called by muse, mutect2, varscan2
- IGF2BP1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987788624; called by muse, mutect2
- IGFBP7 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55272054; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 72/706 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs765719475; called by muse, mutect2, varscan2
- IGLV5-45 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs554672917; called by muse, mutect2
- IGSF9 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63640427; called by muse, mutect2
- IL16 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57265711; called by muse, mutect2
- INSIG2 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55523492; called by muse, mutect2
- ITGA4 | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV52005283; called by muse, mutect2
- ITPK1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs1324693661, COSV50897638; called by muse, mutect2
- JAML | c.628G>C p.G210R (on ENST00000356289 / NM_001098526.2; = p.G200R on NM_153206.3) | Missense Mutation (SNP) | VAF 104/745 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753155654; called by muse, mutect2, varscan2
- KANSL2 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 23/758 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs1371872823; called by muse, mutect2
- KCNC1 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56398209; called by muse, mutect2
- KCNH5 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV59757795; called by muse, mutect2
- KCNN1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55842310; called by muse, mutect2, varscan2
- KCNT1 | c.1412A>T p.Q471L (on ENST00000488444; = p.Q490L on NM_020822.3) | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV99706671; called by muse, mutect2, varscan2
- KRTAP19-3 | c.116G>T p.C39F | Missense Mutation (SNP) | VAF 60/962 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV61854830; called by muse, mutect2
- KRTAP26-1 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1166089622, COSV62128591; called by muse, mutect2
- KRTAP6-3 | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 28/268 reads (10%) | PolyPhen benign (0.345); catalogued as rs113124062; called by muse, mutect2
- KSR2 | c.2195C>A p.P732Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56674130; called by muse, mutect2, varscan2
- LCE2C | c.175A>G p.S59G | Missense Mutation (SNP) | VAF 84/619 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1266672759; called by muse, mutect2, varscan2
- LCT | c.4219G>T p.D1407Y | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51552693; called by muse, mutect2, varscan2
- LENG8 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 114/461 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs763151290; called by muse, mutect2, varscan2
- LILRB4 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs541287083, COSV54403159; called by muse, mutect2
- LIN37 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1200455656; called by muse, varscan2
- LRFN5 | c.2095C>A p.P699T | Missense Mutation (SNP) | VAF 67/345 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53265920; called by muse, mutect2, varscan2
- LRRC15 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs776895651; called by muse, mutect2, varscan2
- MAGEA12 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 98/691 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV100756937; called by muse, mutect2, varscan2
- MAGEB6B | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs371855458; called by muse, mutect2, varscan2
- MAGEL2 | c.1958C>A p.P653Q | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV100045633; called by muse, mutect2, varscan2
- MAP3K4 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 53/428 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as rs541008265; called by muse, mutect2, varscan2
- MCF2L | c.1336G>T p.E446* (on ENST00000375608; = p.E414* on NM_024979.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/176 reads (11%) | catalogued as COSV65051265; called by muse, mutect2, varscan2
- ME2 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV58422877; called by muse, mutect2, varscan2
- MFHAS1 | c.2436G>T p.Q812H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs763634320; called by muse, mutect2, varscan2
- MICAL3 | c.3970G>T p.V1324L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV71588069; called by muse, mutect2
- MN1 | c.3671G>T p.S1224I | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.689); catalogued as rs531489963; called by muse, mutect2, varscan2
- MPO | c.1579C>A p.L527I | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1415283224; called by muse, mutect2, varscan2
- MPP7 | c.1124-1G>T p.X375_splice | Splice Site (SNP) | VAF 51/482 reads (11%) | catalogued as COSV100517231; called by muse, mutect2
- MRC2 | c.4190G>A p.R1397H | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs527861126, COSV57637480; called by muse, mutect2, varscan2
- MS4A7 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as rs756557819, COSV55729142; called by muse, mutect2, varscan2
- MUC2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.15); catalogued as rs534313014, COSV61242409; called by muse, mutect2
- MUC22 | c.4880G>A p.S1627N | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs932854616; called by muse, mutect2
- MYH2 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 64/569 reads (11%) | catalogued as COSV55446758; called by muse, mutect2, varscan2
- MYNN | c.1261G>T p.G421* | Nonsense Mutation (SNP) | VAF 20/238 reads (8%) | catalogued as COSV62992221; called by muse, mutect2
- MYO18B | c.5401C>T p.R1801W | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs980051048, COSV59138727; called by muse, mutect2
- MYO3B | c.1374G>T p.K458N | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100508819; called by muse, mutect2
- NCAM2 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV53107459; called by muse, mutect2
- NDUFA9 | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 31/355 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV56927763; called by muse, mutect2
- NF1 | c.1541A>C p.Q514P | Missense Mutation (SNP) | VAF 56/530 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs775369084, CD1311316, CD962097; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- NFKBID | c.346C>T p.H116Y (on ENST00000396901; = p.H268Y on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/403 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.428); catalogued as rs773596810; called by muse, mutect2, varscan2
- NKD2 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.774); catalogued as rs201002772; called by muse, mutect2
- NLRP2 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 41/588 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV99672515; called by muse, mutect2
- NLRP3 | c.1512C>A p.N504K | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV60232664; called by muse, mutect2, varscan2
- NOBOX | c.794del p.P265Rfs*3 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as COSV99779391; called by mutect2, pindel, varscan2
- NPHP4 | c.1172G>T p.W391L | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100976637; called by mutect2, varscan2
- NR2F2 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 53/616 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67683875; called by muse, mutect2
- NRG2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1371422695; called by muse, mutect2, varscan2
- NTM | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 112/508 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV66186318; called by muse, varscan2
- NUGGC | c.1041G>C p.R347S | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV58432926, COSV58436610; called by muse, mutect2
- NUTM2G | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1255457499; called by muse, mutect2, varscan2
- OBSCN | c.10190G>A p.R3397H | Missense Mutation (SNP) | VAF 61/455 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs559670799, COSV52765980; called by muse, mutect2, varscan2
- OR10K1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99193267, COSV99193596; called by muse, mutect2
- OR14C36 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV100507497; called by muse, mutect2, varscan2
- OR2F1 | c.347C>G p.A116G | Missense Mutation (SNP) | VAF 25/317 reads (8%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.655); catalogued as COSV67331136; called by muse, mutect2
- OR2F1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101231333; called by muse, mutect2, varscan2
- OR2Y1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 29/325 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57136406; called by muse, mutect2
- OR4D5 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.24); catalogued as COSV100190104; called by muse, mutect2, varscan2
- OR52E6 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100259458; called by muse, mutect2
- OR5K4 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 50/416 reads (12%) | catalogued as rs762142876; called by muse, mutect2, varscan2
- OR5L1 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1426143401; called by muse, mutect2
- OR5M11 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 32/460 reads (7%) | catalogued as COSV73141967; called by muse, mutect2
- OR8K1 | c.465T>A p.Y155* | Nonsense Mutation (SNP) | VAF 25/353 reads (7%) | catalogued as rs373186287; called by muse, mutect2
- OR9Q2 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 31/279 reads (11%) | catalogued as rs1462827202; called by muse, mutect2, varscan2
- OTUD6A | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV57974455; called by muse, mutect2, varscan2
- PAPOLB | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV101271290; called by muse, mutect2, varscan2
- PAPPA2 | c.1676G>T p.S559I | Missense Mutation (SNP) | VAF 32/602 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV62773256; called by muse, mutect2
- PAX6 | c.580G>T p.G194* | Nonsense Mutation (SNP) | VAF 70/469 reads (15%) | catalogued as CM068271, COSV53795898; called by muse, mutect2, varscan2
- PCDHA10 | c.2053G>T p.V685L | Missense Mutation (SNP) | VAF 35/584 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100251533; called by muse, mutect2
- PCDHA13 | c.1867C>G p.R623G | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.294); catalogued as COSV56504468; called by muse, mutect2
- PCDHB11 | c.2369G>T p.R790L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs782535816, COSV61310815; called by muse, mutect2
- PCDHGA5 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.195); catalogued as rs188773052, COSV54007929, COSV54051186; called by muse, mutect2
- PCDHGA7 | c.2044G>T p.D682Y | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV53923176; called by muse, mutect2, varscan2
- PCNX3 | c.2552A>T p.N851I | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100856774; called by muse, mutect2
- PCSK2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV52739060; called by muse, mutect2
- PER2 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 65/443 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54523260; called by muse, mutect2, varscan2
- PHACTR1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs773584945, COSV60660085; called by muse, mutect2, varscan2
- PLD5 | c.956C>A p.P319H (on ENST00000442594; = p.P257H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100141448; called by muse, mutect2, varscan2
- PLP1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 109/686 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CX161353; called by muse, mutect2, varscan2
- PMP22 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 22/609 reads (4%) | catalogued as HD070014; called by muse, mutect2
- POU2AF1 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 89/478 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV101260668; called by muse, mutect2, varscan2
- POU3F3 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 30/573 reads (5%) | catalogued as COSV100796878; called by muse, mutect2
- PPP4R4 | c.2285-2A>T p.X762_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as COSV58553244; called by muse, mutect2, varscan2
- PPP6R1 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 76/303 reads (25%) | catalogued as COSV101337009; called by muse, mutect2, varscan2
- PRDM9 | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 70/525 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1451935921; called by muse, mutect2, varscan2
- PRKD1 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as rs1042589965; called by muse, mutect2
- PRMT5 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.288); catalogued as rs1405090024; called by muse, mutect2
- PROX1 | c.1198C>A p.H400N | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.093); catalogued as COSV54776588; called by muse, mutect2, varscan2
- PRUNE2 | c.4189C>T p.P1397S | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs750850110; called by muse, mutect2, varscan2
- PSG2 | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 66/390 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1334438408, COSV61545776; called by muse, varscan2
- PSG9 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 44/526 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52488236; called by muse, mutect2
- PTGS2 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 81/683 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66568831; called by muse, mutect2, varscan2
- QRFPR | c.529G>T p.G177* | Nonsense Mutation (SNP) | VAF 80/504 reads (16%) | catalogued as rs762313039, COSV57676457, COSV57678220; called by muse, mutect2, varscan2
- RALGAPB | c.1788-1G>T p.X596_splice | Splice Site (SNP) | VAF 14/210 reads (7%) | catalogued as COSV53436757; called by muse, mutect2
- RBM15 | c.2618C>G p.S873C | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV63922951; called by muse, mutect2
- RC3H1 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.438); catalogued as rs1216163678; called by muse, mutect2, varscan2
- REG1A | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99286791; called by muse, varscan2
- RFPL1 | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.115); catalogued as COSV62978170; called by mutect2, varscan2
- RFX6 | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV100264244; called by muse, mutect2, varscan2
- RGS12 | c.1979G>T p.R660L | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV60676199; called by muse, mutect2
- RHAG | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 28/741 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57704466, COSV57705617; called by muse, mutect2
- ROBO1 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV71397701; called by muse, mutect2
- ROBO3 | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 97/483 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101185004; called by muse, mutect2, varscan2
- ROR2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 134/655 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100995808, COSV100995931; called by muse, mutect2, varscan2
- RPH3A | c.630G>T p.R210S (on ENST00000389385 / NM_001143854.2; = p.R206S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101231897; called by muse, mutect2, varscan2
- RRP9 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 48/192 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as rs371691265; called by muse, mutect2, varscan2
- SAPCD2 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as COSV68836552; called by muse, mutect2, varscan2
- SCAF4 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 16/446 reads (4%) | catalogued as COSV54585511; called by muse, mutect2
- SCN7A | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101313206; called by muse, mutect2, varscan2
- SCN7A | c.2082G>T p.W694C | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69272950; called by muse, mutect2, varscan2
- SCN8A | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs1263183279, COSV61992632; called by muse, mutect2, varscan2
- SEC14L6 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs765201906, COSV101312577; called by muse, mutect2, varscan2
- SELL | c.308G>T p.G103V (on ENST00000650983; = p.G90V on NM_000655.5) | Missense Mutation (SNP) | VAF 24/602 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357434; called by muse, mutect2
- SEMA5A | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99059485; called by muse, mutect2, varscan2
- SEPHS1 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV59257326; called by muse, mutect2, varscan2
- SH3TC2 | c.1240G>C p.V414L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs138303846; called by muse, mutect2, varscan2
- SIPA1L3 | c.3211G>T p.G1071W | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55923590; called by muse, mutect2
- SIRPB1 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 48/841 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53538122; called by muse, mutect2
- SKAP1 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV100412185; called by muse, mutect2
- SLAIN1 | c.295G>A p.A99T (on ENST00000466548; = p.A121T on NM_001242868.2) | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT tolerated (0.47); catalogued as COSV101022439; called by muse, mutect2, varscan2
- SLAMF8 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs1291768106; called by muse, mutect2
- SLC12A5 | c.320A>T p.N107I (on ENST00000454036 / NM_001134771.2; = p.N84I on NM_020708.5) | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV54800673; called by muse, mutect2, varscan2
- SLC13A4 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs748793188, COSV100818925, COSV62460110; called by muse, mutect2, varscan2
- SLC17A8 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752771712, COSV60122167, COSV60125435; called by muse, mutect2, varscan2
- SLC25A21 | c.891G>C p.E297D | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100492879; called by muse, mutect2
- SLC2A9 | c.1617G>T p.R539S | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV53320210; called by muse, mutect2, varscan2
- SLC30A2 | c.545G>C p.S182T | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs369755786; called by muse, mutect2, varscan2
- SLC4A1 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs1270521728, COSV52261142; called by muse, mutect2, varscan2
- SLCO1C1 | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 55/354 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as rs537883974; called by muse, mutect2, varscan2
- SLITRK3 | c.2045G>T p.R682L | Missense Mutation (SNP) | VAF 41/485 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV53845439; called by muse, mutect2
- SORCS1 | c.894C>G p.S298R | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1245656950; called by muse, mutect2
- SPDYE5 | c.1184C>A p.A395E | Missense Mutation (SNP) | VAF 60/1114 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV71596374; called by muse, mutect2
- SPHKAP | c.2415C>G p.F805L | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV60876953; called by muse, mutect2
- SPINT1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100689274; called by muse, mutect2, varscan2
- SPON1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100115388; called by muse, mutect2
- ST7L | c.418A>G p.R140G | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1381866571; called by muse, mutect2, varscan2
- STAG2 | c.2266-2A>T p.X756_splice | Splice Site (SNP) | VAF 7/141 reads (5%) | catalogued as COSV54354407; called by muse, mutect2
- STAG3 | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 38/455 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV57931526; called by muse, mutect2
- STC2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV54178535; called by muse, mutect2
- SV2A | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as rs1030928966, COSV64964425; called by muse, mutect2
- TAF3 | c.1868G>T p.R623I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV60204785; called by muse, mutect2, varscan2
- TAS2R39 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 42/702 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71471030; called by muse, mutect2
- TBC1D4 | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 24/640 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs1380532393; called by muse, mutect2
- TBC1D7 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs376379585; called by muse, mutect2, varscan2
- TBR1 | c.1396G>T p.G466W | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV67417400; called by muse, mutect2
- TBX20 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.025); catalogued as rs772683573; called by muse, mutect2, varscan2
- TCEAL5 | c.150C>A p.C50* | Nonsense Mutation (SNP) | VAF 35/352 reads (10%) | catalogued as COSV65503125; called by muse, mutect2, varscan2
- TERT | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57242106; called by muse, mutect2
- TEX10 | c.1904G>C p.R635P | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV100887978; called by muse, mutect2, varscan2
- TFAP2A | c.449C>T p.S150L (on ENST00000482890; = p.S142L on NM_001032280.3) | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV60232472; called by muse, mutect2
- TIPRL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/256 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV63208046; called by muse, mutect2
- TMEM151A | c.401C>G p.T134R | Missense Mutation (SNP) | VAF 33/394 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV59173777; called by muse, mutect2
- TMEM181 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs752186985; called by muse, mutect2, varscan2
- TMEM215 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV61363346; called by muse, mutect2
- TMPRSS3 | c.1045G>T p.G349* | Nonsense Mutation (SNP) | VAF 37/465 reads (8%) | catalogued as COSV99368658; called by muse, mutect2
- TNN | c.803T>A p.L268Q | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53431651; called by muse, mutect2
- TNPO2 | c.1939G>C p.G647R | Missense Mutation (SNP) | VAF 23/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100790334; called by muse, mutect2
- TNR | c.4022G>A p.R1341H | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366710466; called by muse, mutect2
- TOP3A | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 86/681 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs374761934, COSV58178159; called by muse, varscan2
- TPI1 | c.835G>A p.V279M (on ENST00000229270; = p.V242M on NM_000365.6) | Missense Mutation (SNP) | VAF 50/681 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs1555132634, COSV51290176; called by muse, mutect2
- TRBV29-1 | c.171C>G p.S57R | Missense Mutation (SNP) | VAF 152/602 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs1339062725; called by muse, mutect2, varscan2
- TRIM14 | c.78G>C p.E26D | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as COSV58354535; called by muse, mutect2, varscan2
- TRIM22 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 21/578 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as COSV66092053; called by muse, mutect2
- TRIM58 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63569126; called by muse, mutect2
- TRPV5 | c.1183G>T p.G395W | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184063055; called by muse, mutect2
- TSGA10IP | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1054043423; called by muse, mutect2, varscan2
- TSHZ3 | c.1630dup p.W544Lfs*38 | Frame Shift Ins (INS) | VAF 58/315 reads (18%) | catalogued as COSV53664501; called by mutect2, pindel, varscan2
- TTC28 | c.2633G>T p.R878L | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67424704; called by muse, mutect2, varscan2
- TTN | c.83584G>T p.A27862S (on ENST00000591111; = p.A20438S on NM_003319.4) | Missense Mutation (SNP) | VAF 90/864 reads (10%) | PolyPhen possibly damaging (0.475); catalogued as COSV60403254; called by muse, mutect2, varscan2
- TTN | c.40063C>A p.R13355S (on ENST00000591111; = p.R5931S on NM_003319.4) | Missense Mutation (SNP) | VAF 45/395 reads (11%) | PolyPhen possibly damaging (0.614); catalogued as COSV60284045; called by muse, mutect2, varscan2
- TTN | c.4994G>T p.G1665V (on ENST00000591111; = p.G1619V on NM_003319.4) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | PolyPhen probably damaging (1); catalogued as COSV60343736; called by muse, mutect2
- UBQLNL | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 21/230 reads (9%) | catalogued as COSV66493124; called by muse, mutect2
- UGGT2 | c.2201-1G>C p.X734_splice | Splice Site (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100948581; called by muse, mutect2, varscan2
- UGT2B17 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100497315; called by muse, mutect2, varscan2
- UGT2B4 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 47/349 reads (13%) | catalogued as COSV59316327; called by muse, mutect2, varscan2
- UNC13A | c.1999G>T p.V667L | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV53189950; called by muse, mutect2, varscan2
- UNC5A | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs761660125; called by muse, mutect2, varscan2
- UNC79 | c.4784C>T p.S1595L (on ENST00000393151 / NM_001346218.2; = p.S1418L on NM_020818.5) | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1447169458; called by muse, mutect2
- USP28 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV50155660; called by muse, mutect2
- USP31 | c.1234+1G>T p.X412_splice | Splice Site (SNP) | VAF 29/156 reads (19%) | catalogued as COSV54850435; called by muse, mutect2, varscan2
- VARS2 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538662804; called by muse, mutect2
- VPS13B | c.7087C>T p.P2363S | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV62156764; called by muse, mutect2, varscan2
- WEE2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 61/668 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770227288, COSV66878549; called by muse, mutect2
- XIRP2 | c.7395G>T p.K2465N (on ENST00000628543; = p.K2640N on NM_152381.6) | Missense Mutation (SNP) | VAF 26/733 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54694403; called by muse, mutect2
- ZC3H13 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs777308536, COSV54457064; called by muse, mutect2
- ZFHX4 | c.3556G>T p.G1186C | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV50851401; called by muse, mutect2
- ZFHX4 | c.4531G>C p.D1511H | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV50698588; called by muse, mutect2, varscan2
- ZFHX4 | c.6041C>A p.P2014Q | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV51476787; called by muse, varscan2
- ZFP37 | c.1637A>T p.E546V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.217); catalogued as rs771033037; called by muse, mutect2, varscan2
- ZFPM2 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 123/1011 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV101022951; called by muse, mutect2, varscan2
- ZGRF1 | c.1363A>G p.I455V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs932981668; called by muse, mutect2, varscan2
- ZMYM3 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs777627986; called by muse, mutect2, varscan2
- ZNF133 | c.897G>A p.M299I (on ENST00000316358 / NM_001352454.2; = p.M298I on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1288747423; called by muse, mutect2
- ZNF141 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as COSV53656456; called by muse, mutect2
- ZNF205 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 67/339 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752405092; called by muse, mutect2, varscan2
- ZNF439 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100397547; called by muse, mutect2, varscan2
- ZNF440 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV100407536, COSV58372130; called by muse, mutect2
- ZNF510 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141866339, COSV99793695; called by muse, mutect2, varscan2
- ZNF526 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV55899970; called by muse, mutect2
- ZNF660 | c.591A>T p.K197N | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1320998227; called by muse, mutect2
- ZNF777 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 90/784 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs749840616, COSV56096468; called by muse, mutect2, varscan2
- ZNF804A | c.2725G>T p.D909Y | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV56476180; called by muse, mutect2
- ZNF804B | c.302C>A p.S101* | Nonsense Mutation (SNP) | VAF 24/420 reads (6%) | catalogued as COSV60825745; called by muse, mutect2
- ZNF804B | c.1217G>T p.R406I | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.641); catalogued as COSV60832227; called by muse, mutect2
- ZNF99 | c.2137G>T p.A713S | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs1283180563; called by muse, mutect2
- ZP4 | c.228G>C p.W76C | Missense Mutation (SNP) | VAF 74/637 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs765491014, COSV99053324; called by muse, mutect2, varscan2
- A2M | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2
- AARS2 | c.2852G>C p.G951A | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); called by muse, mutect2
- ABCA13 | c.11528C>G p.T3843S | Missense Mutation (SNP) | VAF 42/765 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- ABCA13 | c.13322G>T p.G4441V | Missense Mutation (SNP) | VAF 86/482 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA9 | c.3956-1G>T p.X1319_splice | Splice Site (SNP) | VAF 34/200 reads (17%) | called by muse, mutect2, varscan2
- ABCC10 | c.274G>T p.G92W (on ENST00000372530 / NM_001198934.2; = p.G49W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ABCC9 | c.1034A>T p.K345M | Missense Mutation (SNP) | VAF 29/406 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2
- ABLIM3 | c.1788G>T p.R596S | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- AC069544.2 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- AC138647.1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by mutect2, varscan2
- AC138647.1 | c.32C>G p.P11R | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ACKR3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM2A | c.1715G>T p.G572V (on ENST00000219054; = p.G493V on NM_001308169.2) | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, varscan2
- ACTL7B | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM18 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ADAM19 | c.1094C>G p.A365G | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ADAMTS12 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS17 | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS20 | c.5390C>A p.A1797D | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS7 | c.2411A>C p.Y804S | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAR | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY8 | c.2098C>A p.L700M | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ADCYAP1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ADGRA2 | c.599G>C p.W200S | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADGRA3 | c.2965G>T p.E989* | Nonsense Mutation (SNP) | VAF 53/708 reads (7%) | called by muse, mutect2
- ADGRG7 | c.2204T>A p.L735* | Nonsense Mutation (SNP) | VAF 44/429 reads (10%) | called by muse, mutect2, varscan2
- AFF3 | c.1371G>T p.E457D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- AGBL1 | c.1118A>T p.N373I | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); called by muse, mutect2
- AHI1 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.13961G>T p.G4654V | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AKAP6 | c.3890A>G p.Y1297C | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP8L | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); called by muse, mutect2
- ALDH5A1 | c.715G>C p.A239P | Missense Mutation (SNP) | VAF 94/929 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ALKBH7 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ALLC | c.998T>G p.L333R | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ALPK2 | c.5809A>T p.T1937S | Missense Mutation (SNP) | VAF 29/708 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); called by muse, mutect2
- ALPK2 | c.5684T>A p.F1895Y | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- AMDHD2 | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AMER2 | c.428G>T p.R143I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ANGPTL1 | c.628C>A p.H210N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ANK3 | c.11369A>T p.N3790I | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ANKLE1 | c.482A>T p.Q161L (on ENST00000394458; = p.Q107L on NM_152363.6) | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2
- ANKRD11 | c.4786G>T p.E1596* | Nonsense Mutation (SNP) | VAF 55/324 reads (17%) | called by muse, mutect2, varscan2
- ANKRD34C | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- ANKRD60 | c.970A>C p.M324L | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP4B1 | c.2154G>C p.E718D | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- APC2 | c.4396G>T p.E1466* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- APLP1 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.375); called by muse, mutect2
- APOB | c.7723A>G p.K2575E | Missense Mutation (SNP) | VAF 28/686 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- APOB | c.5816C>A p.A1939E | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- ARAP3 | c.3120G>T p.R1040= | Splice Region (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- ARHGAP22 | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 36/583 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ARHGAP25 | c.874A>T p.I292F (on ENST00000409202 / NM_001007231.3; = p.I284F on NM_014882.3) | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ARHGAP28 | c.1262G>C p.R421P (on ENST00000383472 / NM_001366230.1; = p.R262P on NM_001010000.3) | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP4 | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ARHGEF10 | c.1507G>C p.V503L (on ENST00000398564; = p.V478L on NM_014629.4) | Missense Mutation (SNP) | VAF 117/743 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF11 | c.2933A>G p.K978R | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ARID1A | c.1488_1489delinsT p.Q497Nfs*122 | Frame Shift Del (DEL) | VAF 85/921 reads (9%) | called by pindel, varscan2*
- ARL14EPL | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 99/712 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARNTL2 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 30/270 reads (11%) | called by muse, mutect2, varscan2
- ARX | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- ASAP2 | c.2414G>T p.W805L | Missense Mutation (SNP) | VAF 72/546 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ATP11A | c.2219G>A p.S740N | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AUTS2 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- B3GAT1 | c.86T>A p.L29H | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- BABAM1 | c.808A>T p.S270C | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- BHLHE22 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 90/1080 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2
- BIRC6 | c.3550G>T p.G1184W | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3285G>A p.M1095I | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP15 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- BOD1L1 | c.3999G>T p.R1333S | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BPIFB6 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRF2 | c.1259G>T p.*420Lext*20 | Nonstop Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- BRIP1 | c.1674G>A p.W558* | Nonsense Mutation (SNP) | VAF 50/471 reads (11%) | called by muse, mutect2, varscan2
- BTNL9 | c.436T>A p.W146R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BZW1 | c.641G>T p.R214I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- BZW1 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf16 | c.938C>A p.A313E | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); called by muse, mutect2
- C17orf100 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- C18orf63 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C1S | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 44/647 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.302); called by muse, mutect2
- C4orf33 | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- C9 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 58/437 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CACNA1C | c.2104-1G>T p.X702_splice | Splice Site (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- CACNB1 | c.1498T>G p.F500V | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CACNG3 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CADM4 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 40/493 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- CALCRL | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- CAMKMT | c.480G>T p.L160F | Missense Mutation (SNP) | VAF 63/494 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASKIN1 | c.2608G>T p.D870Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CASP8AP2 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CCDC110 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 34/390 reads (9%) | called by muse, mutect2
- CCDC141 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CCDC144A | c.2898G>T p.E966D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.118); called by mutect2, varscan2
- CCDC191 | c.1701G>C p.K567N | Missense Mutation (SNP) | VAF 48/586 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CCDC59 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 78/521 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CCDC89 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 26/342 reads (8%) | called by muse, mutect2
- CCL23 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 59/540 reads (11%) | called by muse, mutect2, varscan2
- CCSER1 | c.633G>T p.L211F | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CCSER1 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 51/319 reads (16%) | called by muse, mutect2, varscan2
- CCT6A | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CD163 | c.1953C>A p.H651Q | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CD200R1 | c.299G>T p.C100F (on ENST00000471858 / NM_170780.3; = p.C123F on NM_138806.4) | Missense Mutation (SNP) | VAF 52/445 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDADC1 | c.866G>T p.S289I | Missense Mutation (SNP) | VAF 47/547 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- CDC14C | c.1592T>A p.L531Q (on ENST00000428251; = p.L424Q on NM_152627.3) | Missense Mutation (SNP) | VAF 38/624 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2
- CDC7 | c.766G>T p.V256F | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.117); called by muse, mutect2
- CDCA2 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CDH12 | c.1869C>A p.C623* | Nonsense Mutation (SNP) | VAF 25/225 reads (11%) | called by muse, varscan2
- CDH17 | c.2192G>A p.R731K | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CDHR3 | c.2318T>G p.M773R | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2
- CEP120 | c.1223A>G p.Q408R | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP126 | c.3309G>T p.L1103= | Splice Region (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- CEP170 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 67/545 reads (12%) | called by muse, mutect2, varscan2
- CEP295 | c.3501A>T p.Q1167H | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2
- CEP295 | c.3643G>T p.E1215* | Nonsense Mutation (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2
- CEP43 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CFAP221 | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CFAP46 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CFAP58 | c.1445T>C p.I482T | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHRM3 | c.334T>A p.C112S | Missense Mutation (SNP) | VAF 59/546 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CHRNB4 | c.894C>A p.Y298* | Nonsense Mutation (SNP) | VAF 49/456 reads (11%) | called by muse, mutect2, varscan2
- CILP2 | c.3323C>A p.P1108Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLCN1 | c.2588T>A p.L863Q | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLEC17A | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); called by muse, varscan2
- CLSTN2 | c.2398C>A p.H800N | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2
- CMTR1 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 105/480 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMTR2 | c.600G>T p.W200C | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMYA5 | c.7465A>T p.N2489Y | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CNMD | c.876C>G p.H292Q | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2
- COL1A2 | c.3105T>G p.A1035= | Splice Region (SNP) | VAF 60/780 reads (8%) | called by muse, mutect2
- COL3A1 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 17/472 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2
- COL4A3 | c.3527G>T p.R1176M | Missense Mutation (SNP) | VAF 23/478 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.251); called by muse, mutect2
- COL4A5 | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 74/711 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 55/523 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CPA2 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 93/487 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CPN2 | c.957G>C p.M319I | Missense Mutation (SNP) | VAF 33/316 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPN2 | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CR1 | c.5291G>T p.S1764I | Missense Mutation (SNP) | VAF 34/552 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CRYM | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 88/532 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CSMD3 | c.9085G>C p.G3029R (on ENST00000297405 / NM_001363185.1; = p.G2860R on NM_052900.3) | Missense Mutation (SNP) | VAF 106/766 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSN3 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CSN3 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 50/700 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2
- CSNK1G2 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- CTNNA2 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 44/555 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.415); called by muse, mutect2
- CTNNA3 | c.1834A>G p.K612E | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CUX2 | c.3943C>G p.P1315A | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYFIP2 | c.1783G>T p.A595S (on ENST00000616178 / NM_001291722.2; = p.A570S on NM_014376.4) | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CYP3A43 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2
- CYP46A1 | c.1042G>T p.G348W | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP4F11 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CYTL1 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2
- DAB2 | c.1400C>A p.S467* | Nonsense Mutation (SNP) | VAF 30/482 reads (6%) | called by muse, mutect2
- DACH1 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DACH2 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); called by muse, varscan2
- DCAF4L2 | c.1041C>A p.H347Q | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- DCAF8 | c.1580G>C p.R527P | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- DCLK1 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDI1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 54/638 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- DDR2 | c.1549G>T p.G517W | Missense Mutation (SNP) | VAF 68/555 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- DDX25 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND1B | c.369A>T p.E123D | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DENND4A | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- DGKI | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DHX16 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 13/227 reads (6%) | called by muse, mutect2
- DIRAS2 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 90/619 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DKK3 | c.962T>A p.L321Q | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DKKL1 | c.564C>A p.H188Q | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); called by muse, mutect2
- DLAT | c.1593A>G p.I531M | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.394); called by muse, mutect2
- DLG2 | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, varscan2
- DMD | c.10953C>A p.D3651E | Missense Mutation (SNP) | VAF 37/614 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2
- DNAAF3 | c.158G>T p.G53V (on ENST00000524407 / NM_001256715.2; = p.G100V on NM_178837.4) | Missense Mutation (SNP) | VAF 24/824 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH11 | c.5255C>A p.T1752K | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, mutect2
- DNAH11 | c.8998C>A p.P3000T | Missense Mutation (SNP) | VAF 59/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.2109_2110del p.S704Ifs*11 (on ENST00000445597; = p.S733Ifs*11 on NM_001367479.1) | Frame Shift Del (DEL) | VAF 18/181 reads (10%) | called by pindel, varscan2
- DNAH8 | c.1592C>A p.P531H | Missense Mutation (SNP) | VAF 44/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH9 | c.10133G>T p.G3378V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC12 | c.120A>T p.E40D | Missense Mutation (SNP) | VAF 35/375 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.092); called by muse, mutect2
- DNAJC16 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2
- DNAJC7 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- DNAJC7 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- DNER | c.1920C>A p.Y640* | Nonsense Mutation (SNP) | VAF 44/568 reads (8%) | called by muse, mutect2
- DPYS | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 25/650 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- DTHD1 | c.1960C>A p.P654T (on ENST00000456874; = p.P489T on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYRK4 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- DYSF | c.3441C>A p.D1147E | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2
- E2F3 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 134/672 reads (20%) | called by muse, varscan2
- EDN3 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2
- EFCAB5 | c.925-1G>T p.X309_splice | Splice Site (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2
- EFCAB8 | c.2721G>T p.K907N | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2
- EFEMP1 | c.898A>T p.T300S | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFLAM | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2
- EIF2S3 | c.631del p.V211Sfs*5 | Frame Shift Del (DEL) | VAF 36/349 reads (10%) | called by mutect2, pindel, varscan2
- EIF2S3B | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 68/896 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EIF5B | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- ELFN1 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELP4 | c.382-2A>T p.X128_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ENPP7 | c.1169T>A p.L390H | Missense Mutation (SNP) | VAF 57/654 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ENTPD4 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPB42 | c.1480T>C p.S494P (on ENST00000441366 / NM_001114134.2; = p.S524P on NM_000119.3) | Missense Mutation (SNP) | VAF 52/616 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2
- EPHA6 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.995); called by muse, mutect2
- EPHB2 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- ERBB4 | c.3765C>A p.H1255Q | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ERICH1 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 57/450 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ERICH6 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ERMAP | c.1128C>A p.N376K | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- ESRRB | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ESYT2 | c.865G>T p.A289S (on ENST00000613624; = p.A213S on NM_020728.3) | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- EVC | c.1082A>T p.Q361L | Missense Mutation (SNP) | VAF 25/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- EYA3 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- EYS | c.2117A>T p.Q706L | Missense Mutation (SNP) | VAF 25/615 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.757); called by muse, mutect2
- F11R | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- FAAP100 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- FAM120C | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 23/451 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.089); called by muse, mutect2
- FAM135B | c.715A>T p.K239* | Nonsense Mutation (SNP) | VAF 52/293 reads (18%) | called by muse, mutect2, varscan2
- FAM166C | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- FAM187A | c.342G>T p.R114S | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- FAT4 | c.10897G>T p.G3633W | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO11 | c.1657A>G p.I553V (on ENST00000403359 / NM_001190274.2; = p.I469V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- FETUB | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- FGD5 | c.4124G>A p.R1375K | Missense Mutation (SNP) | VAF 48/547 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FIG4 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 87/775 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FKBP8 | c.1097A>T p.K366I (on ENST00000222308 / NM_001308373.2; = p.K367I on NM_012181.5) | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- FLAD1 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 49/420 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- FLG | c.957A>T p.R319S | Missense Mutation (SNP) | VAF 66/833 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.867); called by muse, mutect2
- FLG2 | c.5482C>T p.Q1828* | Nonsense Mutation (SNP) | VAF 50/567 reads (9%) | called by muse, mutect2
- FPGS | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- FPR2 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 34/740 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FRAS1 | c.11575G>T p.D3859Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- FRMD6 | c.701A>T p.Y234F (on ENST00000344768 / NM_001267046.2; = p.Y226F on NM_152330.4) | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.717); called by muse, mutect2
- FSIP2 | c.19308C>A p.N6436K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, varscan2
- FSTL4 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 39/444 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- FUT10 | c.377-1G>T p.X126_splice | Splice Site (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- FXYD3 | c.74-2A>T p.X25_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- GABRQ | c.1226C>A p.A409E | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GAGE10 | c.328+1G>T p.X110_splice | Splice Site (SNP) | VAF 87/640 reads (14%) | called by muse, mutect2, varscan2
- GAK | c.3106G>A p.G1036R | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GALNT17 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GALNT17 | c.1266+1G>T p.X422_splice | Splice Site (SNP) | VAF 55/357 reads (15%) | called by muse, mutect2, varscan2
- GALNTL6 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 102/626 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- GAPVD1 | c.1591T>A p.S531T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); called by muse, mutect2
- GBP5 | c.1296T>G p.N432K | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.021); called by muse, mutect2
- GJA10 | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 22/495 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.449); called by muse, mutect2
- GNPAT | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 74/575 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGB1 | c.9443A>T p.Q3148L | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2
- GOLGB1 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 50/547 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GOLM1 | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GP2 | c.1135G>T p.V379L (on ENST00000381362 / NM_001007240.3; = p.V376L on NM_001502.4) | Missense Mutation (SNP) | VAF 46/508 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- GPAM | c.1544A>G p.E515G | Missense Mutation (SNP) | VAF 56/542 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- GPATCH2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- GPKOW | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- GPR151 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GPRC5B | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 84/399 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- GPRIN2 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.082); called by muse, mutect2
- GRM1 | c.3321G>T p.Q1107H | Missense Mutation (SNP) | VAF 106/894 reads (12%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY1A2 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 41/670 reads (6%) | called by muse, mutect2
- GUCY2F | c.983C>A p.T328K | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- H4C8 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- HAVCR2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- HBD | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 58/1032 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- HBD | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 59/1027 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2
- HCFC2 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HCK | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- HELZ | c.1718G>C p.R573T | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- HEMGN | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HERC1 | c.3332A>T p.Q1111L | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2
- HHIPL2 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HHIPL2 | c.209G>C p.C70S | Missense Mutation (SNP) | VAF 99/669 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP3 | c.6320G>T p.G2107V | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HK1 | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 24/774 reads (3%) | called by muse, mutect2
- HMCN1 | c.12854G>T p.G4285V | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA4 | c.940A>T p.T314S | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); called by muse, mutect2
- HPSE | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- HRNR | c.8272G>T p.G2758C | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HRNR | c.4042G>T p.G1348C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by mutect2, varscan2
- HSD17B4 | c.1238G>T p.G413V (on ENST00000414835 / NM_001199291.3; = p.G388V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/443 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- HSD3B2 | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 36/624 reads (6%) | called by muse, mutect2
- HSPA1L | c.411G>T p.L137F | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- HUWE1 | c.5444G>T p.G1815V | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGKV3-7 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 107/929 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IGSF10 | c.3557C>A p.T1186N | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGSF22 | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2
- INPP5K | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- INSIG1 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 39/554 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- IRS2 | c.3956C>T p.T1319I | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ISLR | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITCH | c.803-2A>T p.X268_splice (on ENST00000262650 / NM_001257137.3; = p.X227_splice on NM_031483.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 25/201 reads (12%) | called by muse, mutect2, varscan2
- ITGA10 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 26/449 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ITGB8 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 107/796 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- JPH3 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH3 | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2
- KBTBD11 | c.1653G>C p.Q551H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- KCNC1 | c.169T>A p.F57I | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCND1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.439); called by muse, mutect2
- KCNG2 | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- KCNH2 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 98/588 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, varscan2
- KCNH7 | c.1801G>C p.D601H | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- KCNH8 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 81/544 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ14 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KCNK3 | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- KCNMA1 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 51/560 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, mutect2
- KCNMB2 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 66/396 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNN4 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNU1 | c.2712C>A p.S904R | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KDM5A | c.4587A>T p.K1529N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- KDM7A | c.2228G>A p.G743E | Missense Mutation (SNP) | VAF 76/456 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- KDR | c.1758dup p.G587Wfs*33 | Frame Shift Ins (INS) | VAF 49/355 reads (14%) | called by mutect2, pindel, varscan2
- KIF13A | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21B | c.4746G>T p.E1582D (on ENST00000422435 / NM_001252100.2; = p.E1569D on NM_017596.4) | Missense Mutation (SNP) | VAF 38/576 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- KIFAP3 | c.1577del p.G526Efs*6 | Frame Shift Del (DEL) | VAF 32/316 reads (10%) | called by mutect2, pindel, varscan2
- KLHL34 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.026); called by muse, mutect2
- KLHL6 | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- KMT2B | c.6856G>T p.G2286C | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- KRBA1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT1 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 30/379 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); called by muse, mutect2
- KRT14 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 51/433 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT25 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.12); called by muse, mutect2
- KRT26 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- KRT33B | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT74 | c.184A>T p.N62Y | Missense Mutation (SNP) | VAF 84/853 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- KRT86 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KRTAP10-10 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- KRTAP16-1 | c.1055C>A p.T352N | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- KRTAP9-1 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 45/662 reads (7%) | SIFT tolerated (0.42); called by muse, mutect2
- KRTAP9-7 | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 97/852 reads (11%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- KRTDAP | c.214-1G>T p.X72_splice | Splice Site (SNP) | VAF 40/192 reads (21%) | called by muse, mutect2, varscan2
- KSR1 | c.1663G>T p.E555* (on ENST00000644974 / NM_001367810.1; = p.E440* on NM_014238.2) | Nonsense Mutation (SNP) | VAF 60/560 reads (11%) | called by muse, mutect2, varscan2
- LAMA1 | c.8338G>T p.G2780C | Missense Mutation (SNP) | VAF 24/576 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA2 | c.2046G>T p.K682N | Missense Mutation (SNP) | VAF 92/803 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LAMA5 | c.6362G>T p.G2121V | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- LAMB1 | c.2786T>G p.F929C | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LAMC3 | c.2192C>A p.P731Q | Missense Mutation (SNP) | VAF 135/657 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- LBR | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 18/599 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- LCT | c.4152T>A p.S1384R | Missense Mutation (SNP) | VAF 25/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LEMD3 | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 54/578 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- LEPR | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- LGI2 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 103/515 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LGI3 | c.1240del p.Q414Rfs*4 | Frame Shift Del (DEL) | VAF 77/451 reads (17%) | called by mutect2, pindel, varscan2
- LILRB1 | c.1109C>A p.P370H (on ENST00000427581; = p.P334H on NM_006669.6) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2
- LILRB5 | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LIMCH1 | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 48/232 reads (21%) | called by muse, mutect2, varscan2
- LMX1A | c.193T>A p.C65S | Missense Mutation (SNP) | VAF 100/664 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRIT3 | c.488A>T p.N163I | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP11 | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 29/300 reads (10%) | called by muse, mutect2, varscan2
- LRP1B | c.6291C>A p.Y2097* | Nonsense Mutation (SNP) | VAF 35/183 reads (19%) | called by muse, mutect2, varscan2
- LRPPRC | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- LRRC14B | c.1199T>A p.L400Q | Missense Mutation (SNP) | VAF 65/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LRRC17 | c.371C>A p.A124E | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC19 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- LRRC30 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2
- LRRC37B | c.1658A>T p.Y553F | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- LRRC47 | c.854G>T p.R285M | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2
- LRRC7 | c.27G>T p.R9S | Missense Mutation (SNP) | VAF 23/426 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); called by muse, mutect2
- LRRC7 | c.2810C>A p.S937Y (on ENST00000651989 / NM_001370785.2; = p.S904Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LRRC7 | c.4058T>A p.L1353* | Nonsense Mutation (SNP) | VAF 25/211 reads (12%) | called by muse, mutect2, varscan2
- LRRK2 | c.5402dup p.C1801Wfs*3 | Frame Shift Ins (INS) | VAF 69/477 reads (14%) | called by mutect2, pindel, varscan2
- LSM11 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2
- LTBP2 | c.873C>A p.H291Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LY75 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- LY9 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 78/694 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- LYST | c.507A>T p.E169D | Missense Mutation (SNP) | VAF 25/510 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); called by muse, mutect2
- MAGEA3 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2
- MAGEB1 | c.46C>A p.R16S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MAGEB6B | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 66/708 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2
- MAGI1 | c.3616G>C p.G1206R (on ENST00000402939 / NM_001033057.2; = p.G1235R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/696 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGI2 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.966); called by muse, mutect2
- MAN1A2 | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- MANBA | c.1505A>T p.N502I (on ENST00000642252; = p.N456I on NM_005908.4) | Missense Mutation (SNP) | VAF 29/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP2 | c.4327A>T p.R1443* | Nonsense Mutation (SNP) | VAF 18/446 reads (4%) | called by muse, mutect2
- MARK2 | c.2221G>T p.G741C (on ENST00000402010 / NM_001039469.2; = p.G677C on NM_004954.5) | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MARK3 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 88/573 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM9 | c.3237G>T p.K1079N | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MCTP1 | c.2557-1G>T p.X853_splice | Splice Site (SNP) | VAF 48/380 reads (13%) | called by muse, mutect2, varscan2
- MED27 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 47/698 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- MEGF6 | c.1237G>T p.V413L | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2
- MEGF8 | c.1380G>T p.M460I | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, varscan2
- MEPCE | c.1010A>T p.Q337L | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- METTL18 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MGAM2 | c.262T>A p.W88R | Missense Mutation (SNP) | VAF 75/438 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM2 | c.2347C>A p.R783= | Splice Region (SNP) | VAF 41/224 reads (18%) | called by muse, mutect2, varscan2
- MGAT3 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- MIB2 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIP | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- MLXIP | c.1599G>T p.Q533H | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MPP3 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 48/544 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- MPZL1 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRC1 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 40/535 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MROH7 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- MROH8 | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- MS4A1 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 76/738 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A1 | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 12/334 reads (4%) | called by muse, mutect2
- MS4A7 | c.648+1G>T p.X216_splice | Splice Site (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- MTBP | c.1105A>T p.N369Y | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MUC12 | c.1031G>C p.G344A (on ENST00000379442; = p.G201A on NM_001164462.1) | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- MUC12 | c.5512T>A p.S1838T (on ENST00000379442; = p.S1695T on NM_001164462.1) | Missense Mutation (SNP) | VAF 42/633 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2
- MUC16 | c.15955G>T p.G5319W | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- MUC16 | c.5485C>A p.P1829T | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MUC5B | c.1218C>A p.S406= | Splice Region (SNP) | VAF 10/209 reads (5%) | called by muse, mutect2
- MUC6 | c.2706C>A p.N902K | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2
- MXRA5 | c.4334G>T p.S1445I | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- MYH14 | c.3980T>C p.L1327P | Missense Mutation (SNP) | VAF 78/421 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
884 further variants in this file (372 protein-altering or splice-affecting, 330 silent, 182 other) are not listed here.
